Somatic mutation profile of tumor specimen TCGA-QH-A6X4-01A (aliquot TCGA-QH-A6X4-01A-51D-A32B-08) from TCGA case TCGA-QH-A6X4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 47.2 years (17,258 days).
Specimen TCGA-QH-A6X4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f4bcb20-23bf-4dfb-bfc3-e775834adf7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6X4-10B (Blood Derived Normal), aliquot TCGA-QH-A6X4-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aa80cda-6113-431d-bd64-f6edf9d7e4f5

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Frame Shift Del 2, 3'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AACS | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99908016; called by muse, mutect2, varscan2
- CAPN9 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99680412; called by muse, mutect2, varscan2
- CCR2 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV99432395; called by muse, mutect2, varscan2
- CELF1 | c.899C>T p.S300L (on ENST00000358597 / NM_001376422.1; = p.S296L on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100136937; called by muse, mutect2, varscan2
- CEP120 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.52); catalogued as COSV100071116; called by muse, mutect2, varscan2
- DNAI1 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755853256, COSV99646547; called by muse, mutect2, varscan2
- HNRNPA0 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV100152906; called by muse, mutect2, varscan2
- ITPR3 | c.4513A>G p.T1505A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs757325241, COSV100967367; called by muse, mutect2, varscan2
- MLIP | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs765867577, COSV51436472, COSV99229369; called by muse, varscan2
- MYH7B | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372796334, COSV99482802; called by muse, mutect2, varscan2
- PCDH18 | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV100787316; called by muse, mutect2, varscan2
- PLA2G3 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311697; called by muse, mutect2, varscan2
- PTK7 | c.2006G>A p.S669N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV100030189; called by muse, mutect2, varscan2
- SVIL | c.4031C>T p.S1344F (on ENST00000355867 / NM_021738.3; = p.S918F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100881267; called by muse, mutect2, varscan2
- TXNDC16 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99909240, COSV99909759; called by muse, mutect2, varscan2
- ZNF543 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100386785; called by muse, mutect2, varscan2
- ZNF773 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.78); PolyPhen benign (0.266); catalogued as COSV99989305; called by muse, mutect2, varscan2
- CIC | c.2513del p.V838Gfs*86 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- FUBP1 | c.1691_1694del p.Q564Lfs*100 | Frame Shift Del (DEL) | VAF 16/31 reads (52%) | called by mutect2, pindel, varscan2
- CYP3A43 | c.675C>T p.L225= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1563069818, COSV99733214; called by muse, mutect2, varscan2
- FAIM | c.498T>G p.T166= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs776097159, COSV100623913; called by muse, mutect2, varscan2
- NCAM2 | c.951A>G p.Q317= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99523103, COSV99526193; called by muse, mutect2, varscan2
- SPP2 | c.72C>T p.Y24= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as rs773241018, COSV99394547; called by muse, mutect2, varscan2
- AL136982.4 | n.1548C>T | RNA (SNP) | VAF 41/188 reads (22%) | catalogued as rs764655920; called by muse, varscan2
- OR5H14 | c.*1A>G | 3'UTR (SNP) | VAF 10/18 reads (56%) | catalogued as rs191950026, COSV101454176; called by muse, varscan2
